Gene-level copy-number profile of specimen HCM-CSHL-0603-C18-85M from HCMI case HCM-CSHL-0603-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 69.7 years (25,459 days).
Specimen HCM-CSHL-0603-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dc48605f-8b8f-436b-9e78-c160ac8b91e0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0603-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/92fd7b2e-781d-4bd1-939d-c5653e7611ad

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 709; copy number 2: 14,957; copy number 3: 30,819; copy number 4: 9,384; copy number 5: 872; copy number 6: 30; copy number 7: 1,785; copy number 8: 147; copy number 9: 130; copy number 11: 34; copy number 15: 39; copy number 17: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,139 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:114,922,359–119,179,149, 67 genes, copy number 7 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 7 (broad region; genes not listed).
- chr13:18,467,172–36,131,382, 355 genes, copy number 7–9 (broad region; genes not listed).
- chr13:77,535,674–78,659,155, 22 genes, copy number 7 (within-gene range 7–8): SCEL, AL137140.1, SCEL-AS1, RNY3P7, SPTLC1P5, SLAIN1, MIR3665, EDNRB-AS1, EDNRB, OBI1-AS1, AL139002.1, RN7SL810P, LINC01069, LINC00446, AL138957.1, SRGNP1, RNY3P3, RPL31P54, ELOCP23, AL445209.1, POU4F1, OBI1.
- chr13:78,849,231–81,691,072, 27 genes, copy number 7–8: HSPD1P8, CCT5P2, NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, LINC01038, LINC00382, AL158064.1, LINC01080, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5.
- chr20:21,755,270–23,039,241, 19 genes, copy number 7: RPL41P1, AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4.
- chr20:31,257,664–33,111,751, 77 genes, copy number 11–17 (broad region; genes not listed).
- chr20:34,194,569–34,269,344, 1 gene, copy number 7 (within-gene range 5–7): ASIP.
- chr20:34,234,840–34,311,802, 4 genes, copy number 7: AL035458.2, AL035458.1, AHCY, AL356299.2.
- chr20:34,363,241–36,088,192, 73 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 709. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
